Somatic mutation profile of tumor specimen TARGET-50-PAJLKR-01A (aliquot TARGET-50-PAJLKR-01A-01D) from TARGET case TARGET-50-PAJLKR, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.2 years (2,247 days).
Specimen TARGET-50-PAJLKR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5caffa1-c7d5-48fa-acaf-418d03f35b84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJLKR-11A (Solid Tissue Normal), aliquot TARGET-50-PAJLKR-11A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50e85398-8e92-470c-a364-2fa826d95f63

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC25A44 | c.321T>A p.S107R | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as COSV63961913, COSV63962504; called by muse, mutect2, varscan2
- AL133500.1 | c.1283dup p.K429Efs*27 | Frame Shift Ins (INS) | VAF 40/94 reads (43%) | called by mutect2, pindel, varscan2
- DOP1A | c.2321G>T p.R774L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.019); called by muse, mutect2
- ZNF554 | c.252G>T p.L84= | Splice Region (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SLC25A44 | c.444C>T p.R148= | Silent (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
